Surgical pathology report (de-identified scan), TCGA case TCGA-A7-A5ZX, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-A7-A5ZX-01A (Primary Tumor).

[page 1 of 4]
ICD-O-3
Carcinoma, lobular
infiltrating 8520/3
Site: (L) Breast NOS C50.9
path (L) Breast, upper-
outer quadrant C50.4
JW 4/12/13

Final Surgical Pathology Report

Procedure:

Diagnosis

A. Lymph nodes, left axillary sentinel, excision -
Metastatic carcinoma in two of two (2/2) lymph nodes in this part.

B. Breast, right, excision -
Invasive lobular carcinoma, 0.5 cm in greatest dimension (see
microscopic description, including for prognostic marker results).
Lobular carcinoma-in-situ.
Fibrocystic changes, with microcalcifications present.
Skin, nipple, and deep margin negative for tumor.

C. Breast, left, excision -
Invasive lobular carcinoma, forming a 3.2 cm in greatest dimension
mass, with additional scattered foci of invasive lobular carcinoma
present.
Invasive lobular carcinoma present at least very near (<1 mm from), and
possibly at, the deep margin in the separate foci.
Skin and nipple negative for malignancy.
Lobular carcinoma-in-situ.
Biopsy site changes.
Fibrocystic changes, with microcalcifications present.

D. Lymph nodes, left axillary, excision -
Metastatic carcinoma in nineteen of twenty-two (19/22) lymph nodes in
this part, including with metastatic carcinoma in the superior-most
lymph node.

Microscopic Description:

A, D. There is metastatic carcinoma in two of two (2/2) sentinel lymph
nodes in part A, and in nineteen of twenty-two (19/22) lymph nodes in
part D. Thus overall in this case, there is metastatic carcinoma in
twenty-one of twenty-four (21/24) lymph nodes (pN3a). There is
extracapsular extension. The largest involved lymph node is one of the
sentinel lymph nodes, 2.5 cm in greatest dimension. The largest lymph
node in part D is negative for tumor. There is metastatic carcinoma in
the superior-most lymph node in part D. Please note that in addition
to examining H&E stained sections, immunostains with antibodies to
keratin (AE1-AE3) were examined on representative blocks in both parts
to aid in assessment.

B. The following template summarizes the findings in this part:

Invasive carcinoma: Present

Histologic type: Invasive lobular carcinoma, identified
incidentally in block B4

Histologic grade:

Overall grade: 2

Architectural score: 3

Nuclear score: 2

Mitotic score: 1

Greatest dimension (pT): slightly >0.5 cm (pT1b)

Specimen margins: Negative

Vessel invasion: Not identified

Nipple: Negative for tumor

Invasion of skin or chest wall: Not identified

[page 2 of 4]
Ductal carcinoma in situ: Not identified

Description of non-tumorous breast: Fibrocystic changes, with microcalcifications present
Comments: There is also lobular carcinoma-in-situ present. Please note that immunostains with antibodies to p63, keratin (AE1-AE3), and e-cadherin were examined on representative blocks to aid in assessment.

Distant metastasis (pM): Not applicable

Breast prognostic marker results

Results

Estrogen receptor: 80% / moderate intensity
Progesterone receptor: 5% / weak intensity
Her2 by IHC: 1+

Interpretation

Estrogen receptor: Positive
Progesterone receptor: Weakly positive
Her2 by IHC: Negative for Her2 expression

Comments

Fixation time: 30:00
Cold ischemia time: 0:30

The analyzed tissue met quality requirements of the ASCO/CAP guidelines for Her2 testing. Control materials stained appropriately.

Based on data collected in our laboratory and reported in the literature we recommend FISH analysis for Her2 in cases that stain with intermediate intensity by immunohistochemistry.

Prognostic markers were done by immunohistochemical stain on paraffin sections from 10% neutral buffered formalin fixed tissue using antibodies on a Benchmark automated stainer.

The Her2 antibody is clone 4B5 and has been approved by the FDA as an aid in the assessment of breast cancer patients for whom Herceptin treatment is considered.

This laboratory meets the test validation and quality assurance requirements of the ASCO/CAP guidelines for Her2, ER and PR testing for carcinoma of the breast

C. The following template summarizes the findings in this part:

Invasive carcinoma: Present

Histologic type: Invasive lobular carcinoma. Invasive lobular carcinoma is identified comprising the main mass lesion, as well as in multiple additional foci in random sections of this breast (blocks C7, C8, C10, C11).

Histologic grade:

Overall grade: 2

Architectural score: 3

Nuclear score: 2

Mitotic score: 1

Greatest dimension (pT): The main mass lesion is 3.2 cm in greatest dimension (pT2)

Specimen margins: Although the margins surrounding the main mass lesion are negative, tumor in the additional foci of invasive lobular carcinoma is present at least very near (<1 mm from), and possibly at, the deep margin, with fragmentation hindering assessment.

Vessel invasion: Not identified

Nipple: Negative for tumor

Invasion of skin or chest wall: Not identified

[page 3 of 4]
C. Received fresh (excised at _____ received at _____ placed in formalin at _____ in a container labeled "left breast" is a 20.5 cm from superior to inferior x 18.8 cm from medial to lateral x 3.2 cm from anterior to posterior soft tan-yellow mastectomy specimen, with an orienting suture present. On the anterior surface there is a 7 x 5 cm

[page 4 of 4]
tan-white skin ellipse, with a centrally located 1.2 x 1.2 x 0.5 cm nipple. The intact deep margin is inked, and the specimen is serially sectioned. There is a circumscribed 3.2 x 2.9 x 1.8 cm rubbery tan-white mass within the upper outer quadrant. The lesion is 1.1 cm from the deep margin, and 1.3 cm from the anterior surface, which is subsequently inked blue. The specimen away from the nodule consists of interspersed yellow adipose tissue and tan tissue, without additional focal lesion. RS-12, following fixation.

BLOCK SUMMARY: C1-C3 - tumor to anterior surface; C4,C5 - tumor to deep margin; C6 - central tumor; C7 - upper outer quadrant; C8 - upper inner quadrant; C9 - lower inner quadrant; C10 - lower outer quadrant; C11 - central breast; C12 - nipple.

D. Received fresh in a container labeled "left axillary contents" is a 6.5 x 6.3 x 2.4 cm aggregate of yellow lobular fatty tissue which has a suture designating superior axilla. Dissection of the specimen reveals multiple lymph nodes, up to 3.5 cm in greatest dimension. RS-9, following fixation, with all lymph nodes submitted, from superior to inferior, with the superior-most lymph node in block D1, four lymph nodes in block D2, five lymph nodes in block D3, three lymph nodes in block D4, one sectioned lymph node in blocks D5 & D6, four lymph nodes in block D7, one lymph node in block D8, and three lymph nodes in block D9.

Bilateral disease.

Dual/Synchronous Primary No/mt	☒	☐

Source: NCI Genomic Data Commons file c1ff24a2-a2ba-4ed3-8e4a-54d81dace6f3 (TCGA-A7-A5ZX.A8834D03-81F5-43BC-A4AB-F215C89CB095.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).